Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012426-09A.1 (aliquot TARGET-15-SJMPAL012426-09A.1-01D) from TARGET case TARGET-15-SJMPAL012426, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.4 years (511 days).
Specimen TARGET-15-SJMPAL012426-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07884fb8-427e-4391-9c03-5d5671890b70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012426-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012426-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71cb87c9-f1b3-473a-9545-bddf31806698

The open-access MAF lists 7 somatic variants for this specimen: 1 protein-altering or splice-affecting, 6 silent.
By variant classification: Silent 6, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLCL1 | c.2330T>C p.I777T | Missense Mutation (SNP) | VAF 90/183 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1454732776; called by muse, mutect2, varscan2
- AKR1C1 | c.666C>T p.H222= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs377035250; called by muse, mutect2, varscan2
- C11orf52 | c.240C>T p.D80= | Silent (SNP) | VAF 15/248 reads (6%) | called by muse, mutect2
- NLRP8 | c.699C>T p.Y233= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as rs377108884; called by muse, mutect2, varscan2
- OSBPL11 | c.2052G>T p.S684= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2
- SLC6A14 | c.606C>T p.N202= | Silent (SNP) | VAF 42/43 reads (98%) | catalogued as rs781876726, COSV64148728; called by mutect2, varscan2
- TUBGCP3 | c.1593G>A p.Q531= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as rs1212574211; called by muse, mutect2
